CCDI case PBCUYP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/2fe2614c-2538-4a1c-ab46-a41d8d3bc6df

Demographics
Sex at birth: female.

Biospecimens (4 samples)
- Sample 0E18HH: Tissue type: Tumor; Specimen type: Solid Tissue.
- Samples 0E18HN, 0E2CNV (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0E18I2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
